Somatic mutation profile of tumor specimen TCGA-CJ-4637-01A (aliquot TCGA-CJ-4637-01A-02D-1386-10) from TCGA case TCGA-CJ-4637, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage IV; Tumor grade: G4; Age at diagnosis: 52.3 years (19,101 days).
Specimen TCGA-CJ-4637-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0288e53b-7360-44b2-940c-c4b61c12f3b5.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CJ-4637-11A (Solid Tissue Normal), aliquot TCGA-CJ-4637-11A-01D-1251-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b0ac82e9-1f12-42b5-9f7c-e0639fefb53b

The open-access MAF lists 33 somatic variants for this specimen: 26 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 19, Silent 6, Nonsense Mutation 4, Frame Shift Del 2, RNA 1, Splice Site 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS12 | c.4019G>A p.C1340Y | Missense Mutation (SNP) | VAF 19/249 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV61273279; called by muse, mutect2
- AP3M1 | c.464A>T p.D155V | Missense Mutation (SNP) | VAF 18/278 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.288); catalogued as COSV62332187; called by muse, mutect2
- ARHGAP9 | c.674C>A p.P225H | Missense Mutation (SNP) | VAF 10/90 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.001); catalogued as COSV100712532, COSV62722232; called by muse, mutect2
- BAP1 | c.233A>G p.N78S | Missense Mutation (SNP) | VAF 13/92 reads (14%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.608); catalogued as rs1319729011, CM160681, COSV56232513; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CELF3 | c.374C>T p.T125I | Missense Mutation (SNP) | VAF 20/184 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.844); catalogued as rs1435501736, COSV51885193; called by mutect2, varscan2
- CFAP44 | c.848A>C p.D283A | Missense Mutation (SNP) | VAF 63/405 reads (16%) | SIFT deleterious (0.02); PolyPhen benign (0.058); catalogued as COSV55614571; called by muse, mutect2, varscan2
- CLK4 | c.145T>C p.F49L | Missense Mutation (SNP) | VAF 149/535 reads (28%) | SIFT tolerated (0.72); PolyPhen benign (0); catalogued as COSV60320348; called by muse, mutect2, varscan2
- DOCK4 | c.2866C>T p.R956* | Nonsense Mutation (SNP) | VAF 14/405 reads (3%) | catalogued as COSV101447935, COSV70241535; called by muse, mutect2
- EFCAB13 | c.1214C>G p.S405C | Missense Mutation (SNP) | VAF 24/228 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.785); catalogued as COSV58951361; called by muse, mutect2, varscan2
- ENC1 | c.774G>C p.K258N | Missense Mutation (SNP) | VAF 31/178 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV56630638; called by muse, mutect2, varscan2
- GRID1 | c.815A>C p.H272P | Missense Mutation (SNP) | VAF 41/247 reads (17%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.958); catalogued as COSV60045204; called by muse, mutect2, varscan2
- HDC | c.1253G>T p.C418F | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.25); PolyPhen benign (0.05); catalogued as COSV99984219; called by mutect2, varscan2
- ITGA1 | c.182+1G>T p.X61_splice | Splice Site (SNP) | VAF 22/336 reads (7%) | catalogued as COSV50892308; called by muse, mutect2
- JHY | c.95A>C p.K32T | Missense Mutation (SNP) | VAF 30/409 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.299); catalogued as COSV56221040; called by muse, mutect2
- KLF9 | c.334G>T p.E112* | Nonsense Mutation (SNP) | VAF 28/171 reads (16%) | catalogued as COSV65808024; called by muse, mutect2, varscan2
- KNOP1 | c.1211T>C p.L404P | Missense Mutation (SNP) | VAF 11/66 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs747407192, COSV54929374; called by muse, mutect2, varscan2
- LTBR | c.663G>T p.M221I | Missense Mutation (SNP) | VAF 19/157 reads (12%) | SIFT tolerated (0.36); PolyPhen benign (0.039); catalogued as COSV57439656; called by muse, mutect2, varscan2
- ORC4 | c.1024G>C p.E342Q | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT tolerated (0.14); PolyPhen benign (0.055); catalogued as COSV51576128; called by muse, mutect2, varscan2
- PCDH15 | c.3158C>T p.T1053I | Missense Mutation (SNP) | VAF 14/107 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57366958; called by muse, mutect2, varscan2
- POLN | c.151A>T p.K51* | Nonsense Mutation (SNP) | VAF 56/1438 reads (4%) | catalogued as COSV67026896; called by muse, mutect2
- RASGRP2 | c.1187C>T p.T396M | Missense Mutation (SNP) | VAF 21/104 reads (20%) | SIFT tolerated (0.22); PolyPhen benign (0.081); catalogued as rs768737956, COSV62450512; called by muse, mutect2, varscan2
- SPOCD1 | c.1529T>A p.V510D | Missense Mutation (SNP) | VAF 16/90 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.727); catalogued as COSV57098852; called by muse, mutect2, varscan2
- ST3GAL3 | c.1053T>A p.Y351* (on ENST00000361392 / NM_174964.4; = p.Y336* on NM_006279.5) | Nonsense Mutation (SNP) | VAF 24/146 reads (16%) | catalogued as COSV53518365; called by muse, mutect2, varscan2
- VCP | c.26G>T p.G9V | Missense Mutation (SNP) | VAF 27/202 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.028); catalogued as COSV62721781; called by muse, mutect2, varscan2
- SORL1 | c.3796_3797del p.S1266Rfs*2 | Frame Shift Del (DEL) | VAF 15/151 reads (10%) | called by mutect2, pindel
- VHL | c.349del p.W117Gfs*42 | Frame Shift Del (DEL) | VAF 67/358 reads (19%) | called by mutect2, pindel, varscan2
- ADAMTS5 | c.1497G>A p.L499= | Silent (SNP) | VAF 16/294 reads (5%) | catalogued as rs1232599034, COSV53182803, COSV53183296; called by muse, mutect2
- ANKRD24 | c.366C>T p.A122= | Silent (SNP) | VAF 16/242 reads (7%) | catalogued as rs373820003; called by muse, mutect2
- CXCR2 | c.27C>T p.D9= | Silent (SNP) | VAF 18/243 reads (7%) | catalogued as rs776173448, COSV59281643; called by muse, mutect2
- ERMARD | c.1758T>A p.P586= | Silent (SNP) | VAF 62/627 reads (10%) | catalogued as COSV64648624; called by muse, mutect2, varscan2
- TRAV39 | c.202C>T p.L68= | Silent (SNP) | VAF 17/187 reads (9%) | called by muse, mutect2, varscan2
- TRIP12 | c.135A>G p.Q45= | Silent (SNP) | VAF 17/359 reads (5%) | catalogued as COSV52270105; called by muse, mutect2
- C2orf83 | n.102C>T | RNA (SNP) | VAF 34/215 reads (16%) | catalogued as COSV52312431; called by muse, mutect2, varscan2
